Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01P, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01P-01A (Primary Tumor).

TCGA #:

Sample ID #

Diagnosis:

This is a poorly differentiated adenocarcinoma of the ascending colon with partial neuroendocrine differentiation, with a histopathological grade G3 differentiation, with extensive necroses, with substantial with peritumorous, chronic inflammation, with tumor infiltration in the layers of the colon wall as far as the pericolic fatty connective tissue, with carcinomatous lymphangiosis, with a regional lymph node metastasis (1/21), tumor-free overview sections from the resection margins and from the attached reticular fatty tissue, as well as chronic appendicitis.

According to these prepared sections, the tumor spread of the colon carcinoma corresponds to the tumor stage pT3, pN2, MX, L1

ICD - 0 - 3

Adenocarcinoma, nos 8140/3

Site: ascending colon C18.2 per 3/30/11

Case is (check):		

Kmi

Source: NCI Genomic Data Commons file 32f78a3e-a80e-4aca-983b-64c57e5ad879 (TCGA-AA-A01P.8547AC20-9066-452B-BB3D-AF6618445A79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).